Surgical pathology report (de-identified scan), TCGA case TCGA-06-5411, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-5411-01A (Primary Tumor).

[page 1 of 5]
[REDACTED]

[REDACTED]

Surgical Pathology Report

TCGA-06-5411

=====

CLINICAL HISTORY

[REDACTED] has experienced progressive memory loss, headache, lower extremity weakness, and recently developed [REDACTED]. On imaging, there is a multicystic, enhancing, left frontal tumor that extends across midline.

OPERATIVE DIAGNOSES

Left frontal brain tumor

Operation/Specimen: A: Left frontal tumor, excision biopsy
B: Frontal brain tumor, excision biopsy
C: Brain, excision biopsy

PATHOLOGICAL DIAGNOSIS:

A. Brain, left frontal, excisional biopsy: Brain tissue with focal necrosis and microvascular proliferation.
B and C. Brain, frontal, excisions:
1. Glioblastoma.
2. MIB-1 proliferation index: 50%.
See Microscopy Description and Comment.

COMMENT

Part A is portions of cerebrum, and fragments of necrotic tissue. There is not viable tumor in this specimen.

Parts B and C are portions of cerebrum that are heavily infiltrated and extensively effaced by a glial small cell neoplastic proliferation. The neoplastic cells have nuclear anaplasia, brisk mitotic activity, and a very high proliferation index of about 50% throughout the tumor. There is focal microvascular cellular proliferation, and there are zones of tumor necrosis, some with pseudopalisading.

The neoplasm is a glioblastoma (WHO grade IV).

[page 2 of 5]
PROCEDURES/ADDENDA

MGMT Promoter Methylation

Date Ordered: [REDACTED] Date Reported: [REDACTED]

Interpretation

NEGATIVE: No evidence of methylated MGMT promoter is detected.

Results-Comments

Testing performed on DNA extracted from tumor paraffin block

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter have been shown to benefit from therapy with alkylating agents. Assessment of

MGMT promoter methylation status involves bisulfite treatment of DNA followed

by real-time PCR amplification (MethyLight) of methylated and unmethylated DNA

sequences. The analytic sensitivity of this assay was determined by serial dilution of methylated positive control DNA into unmethylated DNA, and was assessed to be 1% of methylated DNA in the background of unmethylated DNA. Factors such as the presence of >50% non-neoplastic cells in the sample, or extensive tissue necrosis, may preclude the detection of methylated MGMT promoter sequences.

FDA COMMENT: The above data are not to be construed as the results from a stand alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are

provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

Interpretation

[page 3 of 5]
NEGATIVE - No evidence of EGFRvIII mutation is detected

Results-Comments

TEST DESCRIPTION: Testing performed on RNA extracted from tumor paraffin block

The epidermal growth factor receptor (EGFR) is an attractive molecular target in glioblastoma because it is amplified, overexpressed, and/or mutated in up to 40% to 50% of patients. Epidermal growth factor receptor variant III (EGFRvIII) is an oncogenic, constitutively active mutant form of EGFR that is commonly expressed in glioblastoma. Cell culture and in vivo models of glioblastoma have demonstrated EGFRvIII as defining prognostically distinct subgroups of glioblastomas. Additionally, the presence of EGFRvIII has been shown to sensitize tumors to EGFR tyrosine kinase inhibitors when the tumor suppressor protein PTEN is intact. RNA is extracted from formalin fixed, paraffin embedded tissue samples and reverse transcribed to cDNA. The cDNA is then amplified using standard PCR technique for DNA templates. PCR products are detected by gel electrophoresis. The limit of detection of this assay has been determined to be approximately 5 mutant cells in 100 normal cells.

FDA Comment: The above data are not to be construed as the results from a stand alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA ' [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are

provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

[REDACTED]

INTRA-OPERATIVE CONSULTATION

A.

Left frontal tumor, excision biopsy: Necrotic lesion. [REDACTED] Requested viable lesion. Touch preparation smears performed at [REDACTED] and results reported to the Physician of Record.

B.

Frontal brain tumor, excision biopsy: Malignant glioma with extensive necrosis (C/W glioblastoma). [REDACTED] Touch preparation smears performed at

[page 4 of 5]
[REDACTED] and results reported to the Physician of Record.

[REDACTED]

GROSS DESCRIPTION

A.

Left frontal tumor, excision biopsy: Received fresh, one fragment, 1.8 x 0.7 x 0.4 cm. Soft, dark brown, focally white. In total, A1 and A2.

B. Frontal brain tumor, excision biopsy: Received fresh, five fragments, 3.0 x 1.7 x 0.6 cm in aggregate. Soft, glistening, tannish-brown. In total, B1 and B2.

C. Brain, excision biopsy: CONTAINER LABEL: patient's name

FIXATIVE: fresh

GENERAL: Received are two tan-pink to red irregular tissue fragments, aggregating to 1.8 x 1.7 x 0.4 cm.

SECTIONS: 1, NS

[REDACTED]

[REDACTED]

MICROSCOPIC DESCRIPTION

IMMUNOHISTOCHEMISTRY: The GFAP demonstrates a heavy gliofibrillary background. The CD163 highlights heavy infiltration of the tumor by positive cells. The CD34 depicts prominent focal microvascular cellular proliferation.

The NeuN and synaptophysin demonstrate the tumor infiltration and effacement of cerebral cortex. With the MIB-1 there is a proliferation index greater than 50% throughout the tumor.

ICD-9(s):

191.1 191.1

[REDACTED]

Histo Data

Part A: Left frontal tumor, excision biopsy

Taken: [REDACTED]

Received: [REDACTED]

Stain/cnt

Block

Ordered

Comment

[page 5 of 5]
H/E x 1	1
TPS H/E x 1	1
H/E x 1	2
H/E x 1	3

Part B: Frontal brain tumor, excision biopsy

Taken: [REDACTED]	Received: [REDACTED]		
Stain/cnt	Block	Ordered	Comment
CD163 Vector x 1	1	[REDACTED]	
CD34-DA x 1	1		
EGFR-slides x 1	1		
mGFAP-DA x 1	1		
H/E x 1	1		
KP1-DA x 1	1		
MGMT-slides x 1	1		
MIB1-DA x 1	1		
Synap-DA x 1	1		
TPS H/E x 1	1		
H/E x 1	2		
H/E x 1	3		

Part C: Brain, excision biopsy

Taken: [REDACTED]	Received: [REDACTED]		
Stain/cnt	Block	Ordered	Comment
H/E x 1	1	[REDACTED]	

*** End of Report ***

Source: NCI Genomic Data Commons file d1b0797d-b54f-428e-aa5e-bf0766dd6c1b (TCGA-06-5411.3C5B40A1-47CA-4A9D-B967-BFC34BDC785C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).